Somatic mutation profile of tumor specimen C3L-01279-03 (aliquot CPT0104160009) from CPTAC case C3L-01279, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G4; Age at diagnosis: 68.8 years (25,141 days).
Specimen C3L-01279-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b86c367-6f59-42ea-9573-1b55064f839b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01279-31 (Blood Derived Normal), aliquot CPT0105080002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/104e8fd0-bc97-4e31-b932-af8ad9236679

The open-access MAF lists 116 somatic variants for this specimen: 76 protein-altering or splice-affecting, 24 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 24, Intron 12, Frame Shift Del 7, Nonsense Mutation 3, Frame Shift Ins 3, Splice Site 3, Splice Region 2, 5'UTR 2, 3'Flank 1, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SF3B1 | c.2219G>A p.G740E | Missense Mutation (SNP) | VAF 55/151 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as rs776846119, COSV59205460, COSV59217320; called by muse, mutect2, varscan2
- AMER1 | c.1965G>T p.Q655H | Missense Mutation (SNP) | VAF 34/540 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV57666461; called by muse, mutect2
- ANKS1A | c.2806A>G p.I936V | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.61); catalogued as rs897275035; called by muse, mutect2, varscan2
- CHST14 | c.797A>G p.Y266C | Missense Mutation (SNP) | VAF 183/562 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV104402346; called by muse, mutect2, varscan2
- CLIP2 | c.110G>C p.S37T | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0.006); catalogued as rs907323265; called by muse, mutect2, varscan2
- CST4 | c.325C>A p.Q109K | Missense Mutation (SNP) | VAF 91/245 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.658); catalogued as COSV54150154; called by muse, mutect2, varscan2
- ECPAS | c.881A>C p.N294T | Missense Mutation (SNP) | VAF 104/178 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99397455; called by muse, mutect2, varscan2
- FUT9 | c.637A>G p.I213V | Missense Mutation (SNP) | VAF 20/221 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.238); catalogued as rs1408914524; called by muse, mutect2
- GPR155 | c.841C>A p.L281I | Missense Mutation (SNP) | VAF 66/214 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.245); catalogued as rs1426232710; called by muse, mutect2, varscan2
- IFT57 | c.499A>G p.I167V | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs748875077; called by muse, mutect2, varscan2
- KMT2C | c.14509G>A p.A4837T | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771641625, COSV51448425; called by muse, mutect2, varscan2
- KRT84 | c.196del p.A66Qfs*3 | Frame Shift Del (DEL) | VAF 143/587 reads (24%) | catalogued as COSV99231111; called by mutect2, pindel, varscan2
- MRPL1 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 69/221 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.835); catalogued as rs773093254, COSV59674419; called by muse, mutect2, varscan2
- MYO1A | c.2275G>T p.A759S | Missense Mutation (SNP) | VAF 143/576 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as rs1270034722; called by muse, mutect2, varscan2
- NAT8 | c.305T>C p.L102P | Missense Mutation (SNP) | VAF 83/252 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1456463790, COSV55543123; called by muse, mutect2, varscan2
- NT5C1A | c.93G>C p.K31N | Missense Mutation (SNP) | VAF 39/208 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.52); catalogued as COSV104376597; called by muse, mutect2, varscan2
- OTUD4 | c.1240A>G p.T414A (on ENST00000447906 / NM_001366057.1; = p.T349A on NM_001102653.1) | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.53); PolyPhen benign (0.124); catalogued as rs762847543; called by mutect2, varscan2
- PLEKHA6 | c.156G>A p.M52I | Missense Mutation (SNP) | VAF 34/215 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV55339453; called by muse, mutect2, varscan2
- PPP1R9B | c.2344G>T p.V782F | Missense Mutation (SNP) | VAF 19/331 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.565); catalogued as rs776301591; called by muse, mutect2
- REV1 | c.328C>T p.R110* | Nonsense Mutation (SNP) | VAF 42/152 reads (28%) | catalogued as rs866918190, COSV51490381; called by muse, varscan2
- RIMS2 | c.4382G>A p.R1461H (on ENST00000666250 / NM_001348490.2; = p.R1032H on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 81/209 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779912576; called by muse, mutect2, varscan2
- TMOD2 | c.792T>G p.N264K | Missense Mutation (SNP) | VAF 90/236 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs764362316; called by muse, varscan2
- UQCRC1 | c.274T>C p.F92L | Missense Mutation (SNP) | VAF 54/96 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.797); catalogued as COSV52550963; called by muse, mutect2, varscan2
- USP34 | c.548T>C p.I183T | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs1258026980; called by muse, mutect2, varscan2
- ZFP36L2 | c.1252C>T p.P418S | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.018); catalogued as rs750405213; called by muse, mutect2, varscan2
- ATP6V1B2 | c.603+2T>C p.X201_splice | Splice Site (SNP) | VAF 33/105 reads (31%) | called by muse, mutect2, varscan2
- B4GALT6 | c.526_529del p.L176Ifs*2 | Frame Shift Del (DEL) | VAF 47/163 reads (29%) | called by mutect2, pindel, varscan2
- BAP1 | c.792dup p.V265Sfs*19 | Frame Shift Ins (INS) | VAF 181/306 reads (59%) | called by mutect2, pindel*, varscan2*
- BIRC6 | c.12700C>G p.L4234V | Missense Mutation (SNP) | VAF 51/477 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C4orf46 | c.248A>C p.E83A | Missense Mutation (SNP) | VAF 58/220 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.225); called by muse, varscan2
- CHD6 | c.2507A>C p.N836T | Missense Mutation (SNP) | VAF 54/149 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- CHRNA5 | c.303+1G>C p.X101_splice | Splice Site (SNP) | VAF 46/162 reads (28%) | called by muse, mutect2
- CLEC4F | c.467T>C p.L156P | Missense Mutation (SNP) | VAF 82/208 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- COG1 | c.2291T>C p.L764S | Missense Mutation (SNP) | VAF 152/553 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DDX53 | c.538A>C p.I180L | Missense Mutation (SNP) | VAF 75/295 reads (25%) | SIFT tolerated (0.77); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DNAH3 | c.8445C>A p.D2815E | Missense Mutation (SNP) | VAF 93/264 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EHBP1 | c.1854T>G p.D618E | Missense Mutation (SNP) | VAF 56/178 reads (31%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- EML4 | c.451T>G p.S151A | Missense Mutation (SNP) | VAF 62/169 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ENKD1 | c.708C>A p.H236Q | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ERAP1 | c.941T>C p.F314S | Missense Mutation (SNP) | VAF 96/266 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- FBXO34 | c.1701G>C p.Q567H | Missense Mutation (SNP) | VAF 91/249 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- FGD6 | c.1507A>C p.S503R | Missense Mutation (SNP) | VAF 73/305 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, varscan2
- FRMD1 | c.1268G>T p.G423V | Missense Mutation (SNP) | VAF 78/166 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- FTSJ3 | c.2105_2116del p.P702_V706delinsL | In Frame Del (DEL) | VAF 72/298 reads (24%) | called by mutect2, pindel, varscan2
- GRIA3 | c.1175G>T p.G392V | Missense Mutation (SNP) | VAF 94/428 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- HELB | c.3079dup p.T1027Nfs*3 | Frame Shift Ins (INS) | VAF 78/330 reads (24%) | called by mutect2, pindel, varscan2
- HERC2 | c.4805C>G p.P1602R | Missense Mutation (SNP) | VAF 88/301 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- HPS5 | c.3385G>A p.A1129T (on ENST00000349215 / NM_181507.2; = p.A1015T on NM_007216.4) | Missense Mutation (SNP) | VAF 139/341 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- IQCJ | c.400C>T p.Q134* | Nonsense Mutation (SNP) | VAF 47/161 reads (29%) | called by muse, mutect2, varscan2
- KBTBD7 | c.559A>C p.K187Q | Missense Mutation (SNP) | VAF 138/422 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KCTD20 | c.29dup p.D10Efs*14 | Frame Shift Ins (INS) | VAF 13/126 reads (10%) | called by mutect2, pindel, varscan2
- KIRREL1 | c.703C>T p.Q235* | Nonsense Mutation (SNP) | VAF 58/187 reads (31%) | called by muse, mutect2, varscan2
- LRP1 | c.8700A>C p.Q2900H | Missense Mutation (SNP) | VAF 104/201 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAST4 | c.4620del p.A1541Qfs*63 (on ENST00000403625 / NM_001164664.2; = p.A1352Qfs*63 on NM_015183.3) | Frame Shift Del (DEL) | VAF 134/451 reads (30%) | called by mutect2, pindel, varscan2
- MLKL | c.913A>G p.K305E | Missense Mutation (SNP) | VAF 51/157 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NAGPA | c.686C>G p.S229C | Missense Mutation (SNP) | VAF 138/388 reads (36%) | PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- NDC1 | c.2001A>C p.Q667H | Missense Mutation (SNP) | VAF 33/53 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NHLRC3 | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 65/184 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- NLRP2 | c.3025del p.S1009Pfs*10 | Frame Shift Del (DEL) | VAF 188/578 reads (33%) | called by mutect2, pindel, varscan2
- NPSR1 | c.949A>T p.N317Y | Missense Mutation (SNP) | VAF 69/255 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- OR2W3 | c.520G>T p.V174L | Missense Mutation (SNP) | VAF 159/438 reads (36%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- PIK3CG | c.2391A>G p.A797= | Splice Region (SNP) | VAF 35/82 reads (43%) | called by muse, mutect2, varscan2
- RAPGEF4 | c.2323G>T p.D775Y | Missense Mutation (SNP) | VAF 74/221 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RAPGEF6 | c.4303T>A p.S1435T | Missense Mutation (SNP) | VAF 63/176 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- RASGRP3 | c.1229C>G p.P410R (on ENST00000402538 / NM_001349975.2; = p.P409R on NM_015376.2 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/149 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- RRH | c.107-3C>T | Splice Region (SNP) | VAF 92/297 reads (31%) | called by muse, varscan2
- SLCO1B1 | c.1537C>A p.Q513K | Missense Mutation (SNP) | VAF 126/476 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- SPEG | c.4159G>A p.E1387K | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.022); called by muse, varscan2
- SRPRA | c.889del p.S297Afs*28 | Frame Shift Del (DEL) | VAF 79/253 reads (31%) | called by mutect2, pindel, varscan2
- THEM5 | c.188_189del p.C63Ffs*15 | Frame Shift Del (DEL) | VAF 198/682 reads (29%) | called by pindel, varscan2
- TPI1 | c.219del p.D74Tfs*20 (on ENST00000229270; = p.D37Tfs*20 on NM_000365.6) | Frame Shift Del (DEL) | VAF 29/120 reads (24%) | called by mutect2, pindel, varscan2
- TSC22D1 | c.1565T>G p.F522C | Missense Mutation (SNP) | VAF 103/319 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- YTHDC1 | c.1225T>A p.F409I (on ENST00000344157 / NM_001031732.4; = p.F391I on NM_133370.4) | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF12 | c.15+2T>C p.X5_splice | Splice Site (SNP) | VAF 51/131 reads (39%) | called by muse, mutect2, varscan2
- ZNF354C | c.971G>T p.G324V | Missense Mutation (SNP) | VAF 134/323 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF711 | c.1407A>T p.R469S | Missense Mutation (SNP) | VAF 121/513 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- ABCA13 | c.12681C>T p.L4227= | Silent (SNP) | VAF 99/232 reads (43%) | catalogued as rs1028183293; called by muse, mutect2, varscan2
- ABCD4 | c.1704G>A p.Q568= | Silent (SNP) | VAF 45/135 reads (33%) | catalogued as rs141766346; ClinVar: likely benign; called by muse, mutect2, varscan2
- ATP9B | c.1614T>C p.S538= | Silent (SNP) | VAF 169/494 reads (34%) | called by muse, mutect2, varscan2
- C16orf70 | c.996C>G p.A332= | Silent (SNP) | VAF 41/205 reads (20%) | called by muse, mutect2, varscan2
- CACNA1G | c.1647C>T p.G549= | Silent (SNP) | VAF 83/330 reads (25%) | catalogued as rs367919809; called by muse, mutect2, varscan2
- CD74 | c.211C>T p.L71= | Silent (SNP) | VAF 48/251 reads (19%) | called by muse, mutect2, varscan2
- COPA | c.3582T>C p.P1194= | Silent (SNP) | VAF 80/209 reads (38%) | called by muse, mutect2, varscan2
- CPNE6 | c.1308G>C p.S436= | Silent (SNP) | VAF 39/105 reads (37%) | catalogued as COSV99393408; called by muse, mutect2, varscan2
- EEF1A2 | c.585C>T p.G195= | Silent (SNP) | VAF 58/159 reads (36%) | called by muse, mutect2, varscan2
- ICAM5 | c.738C>T p.P246= | Silent (SNP) | VAF 45/171 reads (26%) | catalogued as rs766315761; called by muse, mutect2, varscan2
- KLF10 | c.399T>G p.P133= | Silent (SNP) | VAF 70/220 reads (32%) | called by muse, mutect2, varscan2
- LIPH | c.315T>A p.V105= | Silent (SNP) | VAF 101/289 reads (35%) | called by muse, mutect2, varscan2
- MAGEC3 | c.726A>G p.T242= | Silent (SNP) | VAF 98/200 reads (49%) | called by muse, varscan2
- MOGS | c.891C>T p.Y297= | Silent (SNP) | VAF 141/368 reads (38%) | called by muse, mutect2, varscan2
- NIBAN1 | c.1569C>T p.Y523= | Silent (SNP) | VAF 62/143 reads (43%) | catalogued as rs137891028; called by muse, mutect2, varscan2
- NOBOX | c.669T>G p.P223= | Silent (SNP) | VAF 19/114 reads (17%) | catalogued as COSV99779472; called by muse, mutect2, varscan2
- PCF11 | c.3270A>T p.V1090= | Silent (SNP) | VAF 120/296 reads (41%) | called by muse, mutect2, varscan2
- PCSK7 | c.1038C>A p.I346= | Silent (SNP) | VAF 46/111 reads (41%) | called by muse, mutect2, varscan2
- PF4V1 | c.72C>G p.L24= | Silent (SNP) | VAF 53/174 reads (30%) | called by muse, mutect2, varscan2
- PHKB | c.2979A>G p.P993= | Silent (SNP) | VAF 91/305 reads (30%) | called by muse, mutect2, varscan2
- PITX3 | c.825C>A p.A275= | Silent (SNP) | VAF 43/140 reads (31%) | called by muse, mutect2, varscan2
- PLIN2 | c.492G>A p.L164= | Silent (SNP) | VAF 247/532 reads (46%) | called by muse, mutect2, varscan2
- POU3F4 | c.354G>A p.P118= | Silent (SNP) | VAF 76/276 reads (28%) | called by muse, mutect2, varscan2
- TOPAZ1 | c.3192A>G p.L1064= | Silent (SNP) | VAF 70/118 reads (59%) | called by muse, mutect2, varscan2
- ARHGEF28 | c.-19C>T | 5'UTR (SNP) | VAF 26/87 reads (30%) | catalogued as rs776533245; called by muse, mutect2, varscan2
- CCDC88A | c.5551+435C>G | Intron (SNP) | VAF 61/202 reads (30%) | called by muse, mutect2, varscan2
- IFNAR2 | c.841-87C>A | Intron (SNP) | VAF 49/76 reads (64%) | called by muse, mutect2, varscan2
- KHSRP | c.1889-9C>T | Intron (SNP) | VAF 50/148 reads (34%) | catalogued as rs1370372987; called by muse, mutect2
- KHSRP | c.1889-11C>G | Intron (SNP) | VAF 51/144 reads (35%) | called by muse, mutect2
- LMNA | c.1380+11G>C | Intron (SNP) | VAF 49/662 reads (7%) | called by muse, mutect2
- MID1 | c.-43T>G | 5'UTR (SNP) | VAF 91/340 reads (27%) | called by muse, mutect2, varscan2
- NKX2-1 | chr14:36513171 G>A | 3'Flank (SNP) | VAF 64/165 reads (39%) | called by muse, varscan2
- PARVA | c.400+65A>G | Intron (SNP) | VAF 130/346 reads (38%) | catalogued as rs992156585; called by muse, mutect2, varscan2
- PHLDB2 | c.2873-37del | Intron (DEL) | VAF 36/140 reads (26%) | called by pindel, varscan2
- PHLDB2 | c.2873-35G>T | Intron (SNP) | VAF 36/123 reads (29%) | called by muse, varscan2
- SLC8A3 | c.1785-2990del | Intron (DEL) | VAF 22/79 reads (28%) | catalogued as COSV53691629; called by mutect2, pindel, varscan2
- TRIP4 | chr15:64387449 C>T | 5'Flank (SNP) | VAF 49/145 reads (34%) | catalogued as rs1225449365; called by muse, mutect2, varscan2
- TSPAN32 | c.628-45C>G | Intron (SNP) | VAF 43/113 reads (38%) | called by muse, mutect2, varscan2
- UTP14A | c.103-12del | Intron (DEL) | VAF 80/365 reads (22%) | called by mutect2, pindel, varscan2
- WASHC4 | c.3354+24A>G | Intron (SNP) | VAF 106/398 reads (27%) | called by muse, mutect2, varscan2
